Gene-level copy-number profile of tumor specimen TCGA-D3-A2J6-06A from TCGA case TCGA-D3-A2J6, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 68.6 years (25,074 days).
Specimen TCGA-D3-A2J6-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.e1805b02-bdfd-4949-91f3-3d787385efe7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A2J6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/442845ad-a8ee-4451-a4b5-b45af5bff36b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 20,186; copy number 2: 36,474; copy number 3: 840; copy number 4: 2,017; copy number 5: 37; copy number 6: 33; copy number 9: 145; copy number 11: 1; copy number 13: 27; copy number 16: 3; copy number 20: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A2J6-06A-11D-A192-01): tumor purity 0.71, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:25,962,802–26,234,987, 39 genes: TRIM38, U91328.2, U91328.1, U91328.3, H3P26, H1-1, H3C1, H4C1, H4C2, H3C2, H2AC4, H2BC3, H2AC5P, H3C3, H1-2, HFE, H4C3, H1-6, H2BC4, H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 264 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:98,890,245–99,244,794, 3 genes, copy number 16 (within-gene range 1–16): PLPPR5, AL445433.2, AL445433.1.
- chr1:117,060,326–121,580,524, 102 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr8:124,044,395–124,372,692, 8 genes, copy number 5 (within-gene range 4–5): FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65.
- chr11:69,371,463–71,928,654, 79 genes, copy number 9–20 (broad region; genes not listed).
- chr11:71,938,671–71,939,544, 1 gene, copy number 9: AP002490.2.
- chr13:78,422,823–78,423,192, 1 gene, copy number 11: RPL31P54.
- chr13:86,909,586–87,674,235, 6 genes, copy number 9 (within-gene range 2–9): LINC00430, UBBP5, LIN28AP2, AL360267.2, AL360267.1, MIR4500HG.
- chr13:87,890,172–88,236,969, 3 genes, copy number 9: TET1P1, LINC00373, RPL29P29.
- chr13:88,494,789–90,535,080, 22 genes, copy number 9: LINC00433, AL445984.2, AL445984.1, LINC00560, GRPEL2P1, AL162573.1, LINC00440, LINC01047, TRIM60P13, SP3P, LINC02336, LINC01040, LINC00353, RPL7L1P1, AL355821.1, PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049.
- chr13:91,398,621–92,873,682, 1 gene, copy number 5 (within-gene range 2–5): GPC5.
- chr13:91,994,518–93,227,317, 14 genes, copy number 5: AL162456.1, RNU4ATAC3P, FABP5P4, AL157815.1, GPC5-AS2, AL159152.1, GPC5-IT1, MIR548AS, AL356737.2, AL356737.1, GPC5-AS1, LINC00363, AL354811.2, AL354811.1.
- chr13:93,309,669–93,395,855, 2 genes, copy number 5: AL160159.1, HNRNPA1P29.
- chr13:94,574,054–95,301,475, 13 genes, copy number 6 (within-gene range 2–6): TGDS, GPR180, RNA5SP36, LINC00391, RN7SL585P, SOX21-AS1, SOX21, BRD7P5, RPL21P112, LINC00557, AL139381.1, RNU6-62P, ABCC4.
- chr13:95,433,604–95,579,759, 2 genes, copy number 9: CLDN10, CLDN10-AS1.
- chr17:70,628,917–71,621,436, 7 genes, copy number 6: AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5.

Autosomal genes at a single copy (total copy number 1): 17,765. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
